Gene-level copy-number profile of tumor specimen TCGA-AO-A0J6-01A from TCGA case TCGA-AO-A0J6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.5 years (22,462 days).
Specimen TCGA-AO-A0J6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.6fc05d70-1569-4bfa-bab2-5947d36fd71b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A0J6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/82bc9b90-2c94-4f4b-818d-6852292351b2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 16,721; copy number 2: 33,862; copy number 3: 6,581; copy number 4: 1,668; copy number 5: 728; copy number 6: 222.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A0J6-01A-11D-A036-01): tumor purity 0.66, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,785,454–7,769,706, 1 gene (within-gene range 0–1): CAMTA1.
- chr1:7,008,376–7,441,554, 5 genes: AL512330.1, RNU1-8P, CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1.
- chr2:209,145,241–209,147,687, 1 gene: CRYGFP.
- chr3:52,545,352–52,685,917, 1 gene (within-gene range 0–1): PBRM1.
- chr6:167,796,647–167,979,776, 4 genes: AL009178.3, AFDN-DT, AFDN, HGC6.3.
- chr9:21,638,285–22,029,594, 11 genes (within-gene range 0–1): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene: AL449423.1.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 950 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–4,140,731, 71 genes, copy number 5 (broad region; genes not listed).
- chr4:24,563,193–34,039,914, 87 genes, copy number 5–6 (broad region; genes not listed).
- chr4:86,823,468–89,999,409, 75 genes, copy number 5 (broad region; genes not listed).
- chr4:137,193,756–167,400,762, 442 genes, copy number 5–6 (broad region; genes not listed).
- chr7:70,972–5,513,809, 122 genes, copy number 5 (broad region; genes not listed).
- chr8:37,843,268–43,674,591, 153 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,854. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
